Somatic mutation profile of tumor specimen ALCH-AE1B-TTP1-A (aliquot ALCH-AE1B-TTP1-A-1-0-D-A604-36) from ALCHEMIST case ALCH-AE1B, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.5 years (27,562 days).
Specimen ALCH-AE1B-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9dd23126-fe1e-4ad8-a2d0-5b0542f23c56.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE1B-NB1-A (Blood Derived Normal), aliquot ALCH-AE1B-NB1-A-1-0-D-A604-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f705046b-4d22-40ea-ab3d-046b10964970

The open-access MAF lists 105 somatic variants for this specimen: 73 protein-altering or splice-affecting, 23 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 23, Intron 4, Nonsense Mutation 4, Frame Shift Del 4, RNA 2, Splice Site 2, 5'UTR 1, 5'Flank 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.151-1G>A p.X51_splice | Splice Site (SNP) | VAF 41/272 reads (15%) | hotspot (GDC flag); catalogued as CS014428, CS067079, COSV58682903, COSV58695350, COSV58708670, COSV58717973; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 168/446 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ARID1B | c.3208A>T p.R1070* | Nonsense Mutation (SNP) | VAF 12/319 reads (4%) | catalogued as rs1554231229; called by muse, mutect2
- CCDC172 | c.261G>T p.R87S | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV60937633; called by muse, mutect2, varscan2
- CCN4 | c.527C>A p.P176H | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV51534410; called by muse, mutect2, varscan2
- DDHD1 | c.31A>G p.T11A (on ENST00000323669; = p.T242A on NM_030637.3) | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as rs1292425534; called by muse, mutect2, varscan2
- DLGAP2 | c.1361C>A p.P454H | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70104264; called by muse, mutect2, varscan2
- GLOD4 | c.855G>T p.E285D (on ENST00000301328 / NM_001366247.1; = p.E270D on NM_016080.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/214 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs757518800; called by muse, mutect2, varscan2
- HIVEP1 | c.1121A>G p.Y374C | Missense Mutation (SNP) | VAF 38/324 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200286173; called by muse, varscan2
- KRTAP10-5 | c.94G>T p.G32C | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs782057050; called by muse, mutect2, varscan2
- KRTAP5-3 | c.629G>T p.G210V | Missense Mutation (SNP) | VAF 54/378 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.248); catalogued as COSV101294504; called by muse, varscan2
- LINC02210-CRHR1 | c.155G>T p.R52L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV53276604; called by muse, mutect2, varscan2
- MAGEB17 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as rs763866721, COSV61556951; called by muse, mutect2, varscan2
- MAGEB3 | c.541G>T p.V181F | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as COSV64397563; called by muse, mutect2, varscan2
- MCM10 | c.2089C>T p.R697C (on ENST00000484800 / NM_182751.3; = p.R696C on NM_018518.5) | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs781012938; called by muse, mutect2, varscan2
- MKRN3 | c.647G>T p.W216L | Missense Mutation (SNP) | VAF 61/230 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV58809822; called by muse, mutect2, varscan2
- OR2B2 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs916095940, COSV100308235, COSV57580039; called by muse, mutect2, varscan2
- OR2C3 | c.676G>T p.V226L | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as rs961158096, COSV63574846, COSV63576659; called by muse, mutect2, varscan2
- OR5D18 | c.743C>A p.A248D | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV61736888; called by muse, mutect2, varscan2
- PI4KA | c.4082A>C p.H1361P | Missense Mutation (SNP) | VAF 23/282 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV99746063; called by muse, mutect2
- PLEKHH2 | c.2705G>T p.G902V | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as rs767695358, COSV56749399; called by muse, mutect2, varscan2
- PRMT5 | c.1042C>T p.R348* | Nonsense Mutation (SNP) | VAF 25/196 reads (13%) | catalogued as rs1397689827, COSV53545184; called by muse, mutect2, varscan2
- REPIN1 | c.677G>T p.R226L | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs762668334; called by muse, mutect2, varscan2
- RP1 | c.4777G>T p.D1593Y | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55125781; called by muse, mutect2, varscan2
- SLC12A3 | c.424G>T p.V142L | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs1263244811; called by muse, mutect2, varscan2
- SLC34A2 | c.1606T>A p.F536I | Missense Mutation (SNP) | VAF 47/459 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs1227346120, COSV65942763; called by muse, mutect2, varscan2
- SLC43A2 | c.1138G>T p.V380F | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as COSV56769338; called by mutect2, varscan2
- SLITRK1 | c.534del p.I179Sfs*11 | Frame Shift Del (DEL) | VAF 83/731 reads (11%) | catalogued as COSV65676755; called by mutect2, pindel, varscan2
- TRPV6 | c.2158C>T p.P720S | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs773644051, COSV100844358; called by muse, mutect2
- XKR4 | c.1874G>A p.C625Y | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs756130370, COSV59301026; called by muse, mutect2
- ZDHHC4 | c.987G>T p.E329D | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1184771450; called by muse, mutect2, varscan2
- ADCK1 | c.1389A>T p.R463S | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- ANK2 | c.4009C>T p.H1337Y | Missense Mutation (SNP) | VAF 46/498 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); called by muse, mutect2
- ANO4 | c.2852A>G p.H951R (on ENST00000392977 / NM_001286615.2; = p.H916R on NM_178826.4) | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- AOC1 | c.18G>T p.W6C | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.43); called by muse, varscan2
- AP2S1 | c.116T>G p.V39G | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ARHGEF9 | c.349C>T p.H117Y | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- CCDC91 | c.158G>T p.R53L | Missense Mutation (SNP) | VAF 58/247 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CDCA8 | c.623G>T p.G208V | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- DACH1 | c.514G>T p.V172L | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.975); called by muse, varscan2
- EFNA3 | c.385T>G p.Y129D | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- EPPK1 | c.5047G>T p.A1683S | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HCN4 | c.630G>C p.Q210H | Missense Mutation (SNP) | VAF 168/524 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- HDX | c.1367A>T p.N456I | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- KAT8 | c.870G>C p.E290D | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.311); called by muse, mutect2
- KIF23 | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMB4 | c.2689G>T p.G897C | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LEF1 | c.652G>T p.V218L | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP1B | c.9878G>T p.G3293V | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- LRRTM4 | c.631C>A p.H211N | Missense Mutation (SNP) | VAF 43/266 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEA11 | c.1235C>A p.T412N | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAP3K5 | c.4037G>A p.R1346H | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- PCDHB9 | c.1657G>T p.D553Y | Missense Mutation (SNP) | VAF 80/584 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PDGFB | c.374T>A p.V125E | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDZD2 | c.2221A>G p.I741V | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- PEX26 | c.722A>T p.D241V | Missense Mutation (SNP) | VAF 51/483 reads (11%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- PRSS21 | c.167A>G p.Q56R | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- RYR2 | c.8871A>T p.E2957D | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.038); called by muse, mutect2
- SELENOS | c.559G>T p.G187* | Nonsense Mutation (SNP) | VAF 82/240 reads (34%) | called by muse, mutect2, varscan2
- SEPTIN4 | c.1379C>A p.S460Y | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- SGMS2 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 37/288 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC14A1 | c.115_133del p.T39Lfs*36 | Frame Shift Del (DEL) | VAF 32/369 reads (9%) | called by mutect2, pindel
- SLC39A3 | c.680G>T p.R227L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.219); called by mutect2, varscan2
- SLITRK4 | c.149G>T p.R50I | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- SMIM9 | c.155C>G p.S52C | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- SNAP47 | c.853C>G p.H285D | Missense Mutation (SNP) | VAF 31/236 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- SPG7 | c.621G>T p.R207= | Splice Region (SNP) | VAF 68/462 reads (15%) | called by muse, mutect2, varscan2
- TINF2 | c.1160_1172del p.I387Tfs*4 | Frame Shift Del (DEL) | VAF 61/675 reads (9%) | called by mutect2, pindel
- TMEM174 | c.349G>T p.G117* | Nonsense Mutation (SNP) | VAF 53/441 reads (12%) | called by muse, mutect2, varscan2
- TNKS1BP1 | c.194del p.P65Lfs*17 | Frame Shift Del (DEL) | VAF 11/69 reads (16%) | called by mutect2, pindel, varscan2
- TRHDE | c.1423G>T p.D475Y | Missense Mutation (SNP) | VAF 61/240 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UBASH3B | c.1358-2A>T p.X453_splice | Splice Site (SNP) | VAF 13/100 reads (13%) | called by muse, mutect2, varscan2
- ZNF835 | c.1173G>T p.R391S | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ADCY5 | c.2229C>T p.T743= | Silent (SNP) | VAF 19/153 reads (12%) | catalogued as COSV100567338; called by muse, mutect2, varscan2
- ANKS1B | c.606G>T p.A202= | Silent (SNP) | VAF 76/267 reads (28%) | called by muse, mutect2, varscan2
- APBA2 | c.1212C>A p.V404= | Silent (SNP) | VAF 120/452 reads (27%) | catalogued as rs771775827, COSV67105580; called by muse, mutect2, varscan2
- ARMCX2 | c.867C>G p.S289= | Silent (SNP) | VAF 17/156 reads (11%) | catalogued as COSV57529662; called by muse, mutect2, varscan2
- C5orf63 | c.93T>A p.P31= | Silent (SNP) | VAF 24/185 reads (13%) | called by muse, varscan2
- CACNA1S | c.4857C>T p.P1619= | Silent (SNP) | VAF 18/173 reads (10%) | called by muse, mutect2
- CRNKL1 | c.2328A>G p.K776= | Silent (SNP) | VAF 22/231 reads (10%) | catalogued as rs753165458; called by muse, mutect2
- CSPG4 | c.2565C>A p.G855= | Silent (SNP) | VAF 143/422 reads (34%) | catalogued as COSV100413585; called by muse, mutect2, varscan2
- CTNND2 | c.1482C>A p.G494= | Silent (SNP) | VAF 6/69 reads (9%) | called by muse, mutect2
- DACH1 | c.2176C>T p.L726= (on ENST00000619232 / NM_001366712.1; = p.L472= on NM_004392.6) | Silent (SNP) | VAF 31/270 reads (11%) | catalogued as rs1449445312; called by muse, mutect2, varscan2
- DMD | c.618A>G p.Q206= | Silent (SNP) | VAF 70/538 reads (13%) | catalogued as rs727503865; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- EGFL7 | c.708C>T p.P236= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs371867059; called by mutect2, varscan2
- FAT3 | c.4524A>G p.K1508= | Silent (SNP) | VAF 35/334 reads (10%) | catalogued as rs1410033218; called by muse, mutect2
- FLNA | c.4662G>C p.G1554= | Silent (SNP) | VAF 45/345 reads (13%) | called by muse, mutect2, varscan2
- FOS | c.768C>T p.V256= | Silent (SNP) | VAF 40/386 reads (10%) | catalogued as rs755314164; called by muse, mutect2, varscan2
- GMIP | c.1050G>C p.R350= | Silent (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- JAG2 | c.34C>A p.R12= | Silent (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2
- MAGED1 | c.1575G>T p.G525= | Silent (SNP) | VAF 21/143 reads (15%) | catalogued as rs970520261; called by muse, mutect2, varscan2
- MFSD6L | c.1395C>T p.A465= | Silent (SNP) | VAF 24/256 reads (9%) | catalogued as rs780557056; called by muse, mutect2
- OSGEP | c.57G>T p.V19= | Silent (SNP) | VAF 15/175 reads (9%) | called by muse, mutect2
- PCDHB3 | c.1515C>T p.S505= | Silent (SNP) | VAF 88/628 reads (14%) | called by muse, mutect2, varscan2
- PREB | c.519A>T p.G173= | Silent (SNP) | VAF 38/253 reads (15%) | called by muse, mutect2, varscan2
- TMPRSS9 | c.999C>A p.T333= (on ENST00000648592; = p.T299= on NM_182973.2) | Silent (SNP) | VAF 20/240 reads (8%) | called by muse, mutect2
- AC024651.2 | chr15:97874136 C>A | 5'Flank (SNP) | VAF 37/426 reads (9%) | called by muse, mutect2
- CTCFL | c.1674+938A>G | Intron (SNP) | VAF 36/288 reads (13%) | catalogued as rs1406865934; called by muse, mutect2, varscan2
- FBXL21P | n.828C>T | RNA (SNP) | VAF 8/55 reads (15%) | catalogued as rs999308205; called by muse, mutect2, varscan2
- FOXP3 | c.1147-33G>T | Intron (SNP) | VAF 29/149 reads (19%) | catalogued as COSV100873068; called by muse, mutect2, varscan2
- GVINP1 | n.6749G>A | RNA (SNP) | VAF 14/102 reads (14%) | called by muse, mutect2, varscan2
- KIT | c.1991-32C>T | Intron (SNP) | VAF 22/174 reads (13%) | called by muse, mutect2, varscan2
- PPP3R2 | c.-11A>G | 5'UTR (SNP) | VAF 8/35 reads (23%) | called by muse, varscan2
- STS | c.*24G>T | 3'UTR (SNP) | VAF 19/173 reads (11%) | called by muse, mutect2, varscan2
- USP25 | c.2337+7292G>T | Intron (SNP) | VAF 16/174 reads (9%) | called by muse, mutect2
